Gene-level copy-number profile of tumor specimen ALCH-B34G-TTP1-C from ALCHEMIST case ALCH-B34G, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 71.8 years (26,224 days).
Specimen ALCH-B34G-TTP1-C: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 5edb4a76-edab-4ce3-89f4-ad9d8026d155.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B34G-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,706 have no estimate.
https://portal.gdc.cancer.gov/files/a0fb048b-8eb0-4adf-be61-49cabf75a39c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 68; copy number 1: 4,191; copy number 2: 54,539; copy number 3: 99; copy number 4: 16; copy number 5: 3; copy number 9: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr21:12,999,676–13,067,033, 3 genes, copy number 5: AP001464.1, ANKRD30BP2, RNU6-614P.
- chr22:18,715,815–18,719,341, 1 gene, copy number 9: PPP1R26P4.

Autosomal genes at a single copy (total copy number 1): 1,403. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
